Somatic mutation profile of tumor specimen TCGA-V4-A9EV-01A (aliquot TCGA-V4-A9EV-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EV, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.8 years (21,855 days).
Specimen TCGA-V4-A9EV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ea002b4-2d54-476c-91c9-0ac34e13aa3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EV-10A (Blood Derived Normal), aliquot TCGA-V4-A9EV-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79362f27-0825-4295-a2b5-6d9823739b6a

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 3, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- H2AZ1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs1167095035; called by muse, mutect2, varscan2
- PRKD1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as rs765821685; called by muse, mutect2, varscan2
- CHST2 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBXL13 | c.74G>A p.W25* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- NR3C1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SYNE1 | c.3880C>T p.Q1294* (on ENST00000367255 / NM_182961.4; = p.Q1301* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- EXD1 | c.330A>G p.V110= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs370262959; called by muse, mutect2, varscan2
- HIRA | c.2490G>A p.T830= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs782074548; ClinVar: likely benign; called by muse, mutect2, varscan2
- LINC00174 | n.3163T>A | RNA (SNP) | VAF 6/23 reads (26%) | catalogued as rs1261401321; called by muse, mutect2
